Somatic mutation profile of tumor specimen TARGET-15-SJMLL003311-09A.2 (aliquot TARGET-15-SJMLL003311-09A.2-01D) from TARGET case TARGET-15-SJMLL003311, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 11.9 years (4,330 days).
Specimen TARGET-15-SJMLL003311-09A.2: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a4447aa6-d8d9-453c-86eb-8d7366d93aaa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMLL003311-14A (Bone Marrow Normal), aliquot TARGET-15-SJMLL003311-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a6bb2528-ffb0-4b25-afc9-002e203cb569

The open-access MAF lists 14 somatic variants for this specimen: 10 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 3, Nonsense Mutation 1, Splice Site 1, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.2028C>G p.N676K | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519766, COSV54042688, COSV54051954; ClinVar: likely pathogenic; called by muse, mutect2
- DACH2 | c.553C>T p.R185C | Missense Mutation (SNP) | VAF 42/85 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748018424, COSV100912997, COSV99058303; called by muse, mutect2, varscan2
- VWF | c.4579C>T p.R1527W | Missense Mutation (SNP) | VAF 122/247 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs747570522; called by muse, mutect2, varscan2
- FNDC3B | c.3539C>A p.A1180E | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- HNRNPUL1 | c.2263-8C>A | Splice Region (SNP) | VAF 4/44 reads (9%) | called by muse, mutect2
- MPHOSPH9 | c.3133+1G>T p.X1045_splice | Splice Site (SNP) | VAF 5/59 reads (8%) | called by muse, mutect2
- NEGR1 | c.28G>T p.A10S | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.757); called by muse, mutect2, varscan2
- PCDH9 | c.793G>T p.A265S | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.82); PolyPhen benign (0.263); called by muse, mutect2
- TOPBP1 | c.1103G>T p.G368V | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- WT1 | c.869_876dup p.P293* | Nonsense Mutation (INS) | VAF 10/18 reads (56%) | called by mutect2, varscan2
- GSDMD | c.183C>A p.I61= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as rs760019831; called by mutect2, varscan2
- HECA | c.516C>A p.A172= | Silent (SNP) | VAF 4/28 reads (14%) | called by muse, mutect2, varscan2
- RBSN | c.456G>T p.V152= | Silent (SNP) | VAF 3/19 reads (16%) | called by muse, mutect2
- COL4A2 | c.1340-275C>G | Intron (SNP) | VAF 14/62 reads (23%) | catalogued as rs9521779; called by muse, varscan2
